MMRF case MMRF_2017 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2ec27dee-37a7-4043-8bc1-a20c73d0e22b

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 82 years; Vital status: Dead; Days to death: 421 days (1.2 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 82.7 years (30,211 days); ISS stage: III; Days to last known disease status: 421 days (1.2 years); Days to last follow up: 421 days (1.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 188 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 258 days; Days to treatment end: 366 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 366 days (1.0 years); Days to treatment end: 400 days (1.1 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 372 days (1.0 years); Days to treatment end: 410 days (1.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 421.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 1): M Protein 8.44 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 66.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 102 g/L; Immunoglobulin A 0.0625 g/L; Immunoglobulin M 0.0433 g/L; Beta 2 Microglobulin 12.8 µg/mL; Lactate Dehydrogenase 1.48 µkat/L; Hemoglobin 5.02 mmol/L; Leukocytes 7.72 ×10⁹/L; Absolute Neutrophil 2.77 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 137 µmol/L; Calcium 2.15 mmol/L; Albumin 28 g/L; Total Protein 15.5 g/dL; Glucose 5.5 mmol/L; C-Reactive Protein 0.006 mg/dL.
- Day 83 (ECOG 1): M Protein 3.55 g/dL; Immunoglobulin G 41.8 g/L; Immunoglobulin A 0.0674 g/L; Immunoglobulin M 0.0444 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 5.69 ×10⁹/L; Absolute Neutrophil 1.41 ×10⁹/L; Platelets 296 ×10⁹/L; Creatinine 102 µmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 9.8 g/dL; Glucose 6.82 mmol/L.
- Day 167 (ECOG 1): M Protein 4.86 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.114 mg/dL; Immunoglobulin G 70.7 g/L; Immunoglobulin A 0.0625 g/L; Immunoglobulin M 0.0433 g/L; Beta 2 Microglobulin 8.84 µg/mL; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 9.79 ×10⁹/L; Absolute Neutrophil 4.57 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 102 µmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 11.3 g/dL; Glucose 7.21 mmol/L.
- Day 258 (ECOG 1): M Protein 6.36 g/dL; Immunoglobulin G 87.4 g/L; Immunoglobulin A 0.0597 g/L; Immunoglobulin M 0.0566 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 9.72 ×10⁹/L; Absolute Neutrophil 3.99 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 106 µmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 13.8 g/dL; Glucose 6.11 mmol/L.
- Day 349 (ECOG 1): M Protein 6.5 g/dL; Immunoglobulin G 77.4 g/L; Immunoglobulin A 0.0783 g/L; Immunoglobulin M 0.0525 g/L; Lactate Dehydrogenase 1.5 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 9.18 ×10⁹/L; Absolute Neutrophil 2.34 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 110 µmol/L; Calcium 1.88 mmol/L; Albumin 31 g/L; Total Protein 12.1 g/dL; Glucose 4.9 mmol/L.

Other clinical attributes
- Day -14: Weight: 64 kg; Height: 158 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_2017_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_2017_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
- Sample MMRF_2017_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 258 days.
